Somatic mutation profile of tumor specimen 0DFSSI from CCDI case PBBRLV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 0.7 years (250 days).
Specimen 0DFSSI: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 93f8a608-c87a-449f-8ee5-75ed056361d2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DFSRZ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/20bb2814-962d-433e-ae37-9280e6c767bf

The open-access MAF lists 7 somatic variants for this specimen: 3 protein-altering or splice-affecting, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, 3'UTR 2, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KMT2D | c.15536G>C p.R5179P | Missense Mutation (SNP) | VAF 219/523 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as CM105472, COSV56428259, COSV56447076, COSV56496109; called by muse, varscan2
- NOP56 | c.1180G>A p.G394R | Missense Mutation (SNP) | VAF 418/1026 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771888944; called by muse, varscan2
- WDR90 | c.926C>T p.P309L | Missense Mutation (SNP) | VAF 191/445 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV99554200; called by muse, varscan2
- AC005833.1 | c.*83A>T | 3'UTR (SNP) | VAF 22/111 reads (20%) | called by muse, varscan2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 16/180 reads (9%) | called by muse, varscan2
- CRIPT | c.*53T>A | 3'UTR (SNP) | VAF 88/759 reads (12%) | called by muse, varscan2
- LARP4 | c.1334+88A>C | Intron (SNP) | VAF 12/106 reads (11%) | called by muse, varscan2
